Somatic mutation profile of tumor specimen TCGA-2G-AALY-01A (aliquot TCGA-2G-AALY-01A-11D-A42Y-10) from TCGA case TCGA-2G-AALY, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3ea3d03-9621-4376-8a93-7ff0b10dd546.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALY-10A (Blood Derived Normal), aliquot TCGA-2G-AALY-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64091dc0-fe26-448b-a1e1-702e7a5451bc

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AACS | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs146784734; called by muse, mutect2, varscan2
- CC2D1A | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58785281; called by muse, mutect2
- EIF3A | c.1175A>G p.N392S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs1439346338; called by muse, mutect2, varscan2
- MAN2B2 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as rs752918524; called by muse, mutect2, varscan2
- PIEZO1 | c.6868C>T p.R2290W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1036733100, COSV56336033; called by muse, mutect2
- TAAR2 | c.370C>A p.L124M (on ENST00000367931 / NM_001033080.1; = p.L79M on NM_014626.3) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.338); catalogued as COSV51580104; called by muse, mutect2
- CCL5 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- FUT8 | c.1700A>G p.Y567C (on ENST00000360689 / NM_001371534.1; = p.Y404C on NM_004480.4) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRNR | c.2818C>G p.Q940E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LHX5 | c.398-1G>A p.X133_splice | Splice Site (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- USP48 | c.2699A>G p.D900G | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ATP5PF | c.48C>T p.A16= | Silent (SNP) | VAF 34/236 reads (14%) | catalogued as rs771159388; called by muse, mutect2, varscan2
- CHAMP1 | c.2370G>T p.R790= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- DYNC2H1 | c.9327G>A p.L3109= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV100518159; called by muse, mutect2, varscan2
- IPO5 | c.2370T>C p.F790= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
